CPTAC case C3L-07535 — Stomach — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f037cda9-3c05-4778-b235-01c2a95dc432

Demographics
Sex at birth: female; Race: white; Year of birth: 1947; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Body of stomach; Age at diagnosis: 74.3 years (27,130 days); Year of diagnosis: 2021; AJCC staging edition: 8th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Residual disease: R0; Days to last known disease status: 1,031 days (2.8 years); Progression or recurrence: no; Days to last follow up: 1,031 days (2.8 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 9.5 cm; Lymph node involvement: Positive; Lymph nodes positive: 1; Lymph nodes tested: 35.
   Treatment given: Treatment type: Chemotherapy; Days to treatment start: 19 days; Days to treatment end: 257 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Days to treatment start: 1,115 days (3.1 years); Days to treatment end: 1,353 days (3.7 years); Treatment outcome: Complete Response.

Follow-up (2 entries)
- Days to follow up: 358 days; Disease response: Complete Response; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 712 days (1.9 years); Disease response: Complete Response; Karnofsky performance status: 90; ECOG performance status: 1.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-07535-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 13 days; Initial weight: 235 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-07535-23: Section location: Body; Percent tumor nuclei: 70; Percent necrosis: 2.
- Sample C3L-07535-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 14 days; Method of sample procurement: Blood Draw.
